Somatic mutation profile of tumor specimen MMRF_2140_1_BM_CD138pos (aliquot MMRF_2140_1_BM_CD138pos_T1_KHS5U_L08716) from MMRF case MMRF_2140, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.0 years (24,110 days).
Specimen MMRF_2140_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20cc6622-2e97-4dc3-8f2f-9e85304d57da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2140_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2140_1_PB_Whole_C3_KHS5U_L08715; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9eb05913-770a-4d24-a13e-a11f1152bb6d

The open-access MAF lists 86 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 19, Intron 11, Silent 9, 5'Flank 5, Splice Site 2, RNA 2, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD26 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV65774940, COSV65775491; called by muse, mutect2, varscan2
- CALML5 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV66702592; called by muse, mutect2, varscan2
- CDH17 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs763186951, COSV50345009; called by muse, mutect2, varscan2
- CDK11B | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.915); catalogued as rs1355162260, COSV52363376; called by muse, varscan2
- CLIP2 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs782633882, COSV56287905; called by muse, mutect2, varscan2
- DMRTA2 | c.1451C>G p.A484G | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV101288902; called by muse, mutect2, varscan2
- F8 | c.671-1G>A p.X224_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as rs1255271151; called by muse, mutect2
- GABRA2 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1272698577; called by muse, mutect2, varscan2
- IGLV1-40 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.414); catalogued as rs766639890; called by muse, varscan2
- IGLV3-1 | c.53T>A p.V18E | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs61736464; called by muse, varscan2
- IGLV4-60 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as rs375413070; called by muse, mutect2, varscan2
- MMS19 | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.072); catalogued as rs1289767638, COSV59135243; called by muse, mutect2, varscan2
- STC1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs766303009, COSV51687571; called by muse, mutect2, varscan2
- TIMM13 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868780870; called by muse, mutect2, varscan2
- ZNF521 | c.2634C>A p.D878E | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0.02); catalogued as COSV64121515; called by muse, mutect2, varscan2
- AC004593.2 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- C15orf39 | c.412C>G p.L138V | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- C8B | c.533+2T>A p.X178_splice | Splice Site (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- CHAF1A | c.2144T>A p.L715Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- CTSO | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CYLD | c.667dup p.M223Nfs*31 | Frame Shift Ins (INS) | VAF 39/59 reads (66%) | called by mutect2, pindel, varscan2
- DAZAP1 | c.482T>C p.F161S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GARNL3 | c.1594A>T p.M532L | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR162 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HASPIN | c.1691G>A p.C564Y | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHV2-70D | c.323C>G p.P108R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, varscan2
- IGHV2-70D | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, varscan2
- IGLV7-43 | c.283A>C p.T95P | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- IGSF3 | c.3389T>C p.F1130S (on ENST00000369486 / NM_001007237.3; = p.F1150S on NM_001542.4) | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OGT | c.1607A>G p.N536S | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHOXF1 | c.343G>C p.V115L | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RS1 | c.673T>G p.*225Gext*43 | Nonstop Mutation (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2
- SCN7A | c.1858C>G p.L620V | Missense Mutation (SNP) | VAF 77/150 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SLC35E2B | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SPAG17 | c.2986_2988del p.E996del | In Frame Del (DEL) | VAF 64/145 reads (44%) | called by pindel, varscan2
- SYCP2L | c.1787C>G p.T596S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- TACR3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- AC020907.6 | c.36G>A p.L12= | Silent (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- CCNF | c.1341C>T p.Y447= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs777340745, COSV53537722; called by muse, mutect2, varscan2
- CSNK2A3 | c.789T>C p.I263= | Silent (SNP) | VAF 55/125 reads (44%) | called by muse, mutect2, varscan2
- CYP4F3 | c.1168A>C p.R390= | Silent (SNP) | VAF 67/157 reads (43%) | catalogued as rs895978967; called by muse, mutect2, varscan2
- EXOC6B | c.1518C>T p.Y506= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs374318382; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNH5 | c.582G>A p.Q194= | Silent (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- LAMB1 | c.498C>T p.F166= | Silent (SNP) | VAF 88/170 reads (52%) | catalogued as rs766542299, COSV55968842; called by muse, mutect2, varscan2
- MRPS16 | c.237C>T p.C79= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as rs1293618271, COSV60285174; called by muse, mutect2
- TP73 | c.1149G>A p.Q383= | Silent (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- AHR | c.*1478T>A | 3'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- AHR | c.*1573T>C | 3'UTR (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2
- BICC1 | c.*924del | 3'UTR (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- C1orf109 | c.456-70C>T | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2
- CA12 | c.*2608G>A | 3'UTR (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- CDR1 | chrX:140784772 A>T | 5'Flank (SNP) | VAF 5/10 reads (50%) | called by muse, varscan2
- CYB5R2 | chr11:7674213 T>C | 5'Flank (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- DGAT2L6 | c.*539T>C | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- DIAPH2 | c.*3933A>T | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- ECHDC2 | c.364+49G>A | Intron (SNP) | VAF 2/12 reads (17%) | catalogued as rs1474247018; called by muse, mutect2
- FAM124A | c.101-6088G>A | Intron (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2
- FAM183BP | n.290G>A | RNA (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- FKBP15 | c.*3870A>T | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22887810 T>C | 5'Flank (SNP) | VAF 10/11 reads (91%) | called by muse, mutect2, varscan2
- KCNA6 | c.-548C>T | 5'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- KIR3DL1 | chr19:54832743 G>A | 3'Flank (SNP) | VAF 31/114 reads (27%) | catalogued as rs759538677; called by muse, varscan2
- LGALS12 | c.*209C>A | 3'UTR (SNP) | VAF 14/63 reads (22%) | catalogued as rs569390416; called by muse, mutect2, varscan2
- LRRC66 | c.*500C>G | 3'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- LTB | c.209-53G>C | Intron (SNP) | VAF 31/51 reads (61%) | called by muse, mutect2, varscan2
- LYPLA2P1 | n.670C>A | RNA (SNP) | VAF 52/88 reads (59%) | called by muse, mutect2, varscan2
- MACF1 | c.221-26580G>A | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- MAP3K7 | c.*264T>A | 3'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- MECOM | c.-189-1280T>G | Intron (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- MSN | c.*2037C>T | 3'UTR (SNP) | VAF 91/198 reads (46%) | called by muse, mutect2, varscan2
- MYOCD | c.2246-30T>G | Intron (SNP) | VAF 41/67 reads (61%) | called by muse, mutect2, varscan2
- NHLH2 | c.-8-398G>C | Intron (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- OSBPL5 | c.1622-269C>T | Intron (SNP) | VAF 5/46 reads (11%) | catalogued as rs972338180; called by muse, mutect2
- PREX2 | c.*75T>C | 3'UTR (SNP) | VAF 59/112 reads (53%) | called by muse, mutect2, varscan2
- PRG4 | c.*299C>A | 3'UTR (SNP) | VAF 109/166 reads (66%) | called by muse, mutect2, varscan2
- RHOT1 | chr17:32142213 C>T | 5'Flank (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- RUFY4 | c.*66T>A | 3'UTR (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- SERBP1 | c.*66A>C | 3'UTR (SNP) | VAF 42/113 reads (37%) | called by muse, mutect2, varscan2
- SHISA2 | c.*264C>T | 3'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- SPECC1 | c.2498-113C>T | Intron (SNP) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- SRRT | c.*34T>A | 3'UTR (SNP) | VAF 13/341 reads (4%) | catalogued as COSV99573920; called by muse, mutect2
- TFPI2 | c.*494G>C | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- TNFSF4 | c.153+1671G>C | Intron (SNP) | VAF 250/397 reads (63%) | catalogued as COSV99919288; called by muse, mutect2, varscan2
- TTC41P | chr12:103915939 A>G | 5'Flank (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- ZNF282 | c.*179C>A | 3'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
